MMRF case MMRF_2597 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/f62ffd84-6300-4c41-9aa5-d50d29c30215

Demographics
Sex at birth: female; Ethnicity: hispanic or latino; Age at index: 64 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 64.6 years (23,599 days); ISS stage: I; Days to last known disease status: 645 days (1.8 years); Days to last follow up: 645 days (1.8 years).
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 106 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 149 days; Days to treatment end: 149 days.
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 261 days; Days to treatment end: 288 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 290 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -6: M Protein 3.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 330 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.883 mg/dL; Immunoglobulin G 39.3 g/L; Immunoglobulin A 1.26 g/L; Immunoglobulin M 0.42 g/L; Beta 2 Microglobulin 2.77 µg/mL; Lactate Dehydrogenase 1.93 µkat/L; Hemoglobin 5.7 mmol/L; Leukocytes 10 ×10⁹/L; Absolute Neutrophil 6.4 ×10⁹/L; Platelets 322 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 5.07 mmol/L; Calcium 2.35 mmol/L; Albumin 41 g/L; Total Protein 10.3 g/dL.
- Day 86 (ECOG 0): Lactate Dehydrogenase 2.77 µkat/L; Hemoglobin 6.82 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 2.29 ×10⁹/L; Platelets 149 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 6.28 mmol/L; Calcium 2.3 mmol/L; Albumin 40 g/L; Total Protein 6.2 g/dL.
- Day 176: Lactate Dehydrogenase 3.8 µkat/L; Hemoglobin 6.08 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 2.15 ×10⁹/L; Platelets 203 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 4.46 mmol/L; Calcium 2.25 mmol/L; Albumin 40 g/L; Total Protein 5.7 g/dL; Glucose 5.34 mmol/L.
- Day 246: Lactate Dehydrogenase 2.78 µkat/L; Hemoglobin 7.38 mmol/L; Leukocytes 6.1 ×10⁹/L; Absolute Neutrophil 3.89 ×10⁹/L; Platelets 250 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 6.53 mmol/L; Calcium 2.45 mmol/L; Albumin 44 g/L; Total Protein 6.9 g/dL.
- Day 372: Serum Free Immunoglobulin Light Chain, Kappa 3.94 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.81 mg/dL; Immunoglobulin G 11.6 g/L; Immunoglobulin A 0.76 g/L; Immunoglobulin M 0.11 g/L; Lactate Dehydrogenase 2.8 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 1.47 ×10⁹/L; Platelets 159 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 6.35 mmol/L; Calcium 2.25 mmol/L; Albumin 42 g/L; Total Protein 6.9 g/dL.
- Day 457 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 3.51 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.58 mg/dL; Immunoglobulin G 12 g/L; Immunoglobulin A 0.89 g/L; Immunoglobulin M 0.08 g/L; Lactate Dehydrogenase 2.42 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 1.68 ×10⁹/L; Platelets 145 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 7.78 mmol/L; Calcium 2.38 mmol/L; Albumin 46 g/L; Total Protein 7.1 g/dL.
- Day 547 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 3.44 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.12 mg/dL; Immunoglobulin G 11.1 g/L; Immunoglobulin A 0.96 g/L; Immunoglobulin M 0.07 g/L; Lactate Dehydrogenase 2.13 µkat/L; Hemoglobin 7.38 mmol/L; Leukocytes 2.6 ×10⁹/L; Absolute Neutrophil 1.2 ×10⁹/L; Platelets 142 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.25 mmol/L; Albumin 42 g/L; Total Protein 6.2 g/dL.
- Day 645 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 3.11 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.24 mg/dL; Immunoglobulin G 10.7 g/L; Immunoglobulin A 1.08 g/L; Immunoglobulin M 0.09 g/L; Lactate Dehydrogenase 2.25 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 2.6 ×10⁹/L; Absolute Neutrophil 1.14 ×10⁹/L; Platelets 154 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 7.64 mmol/L; Calcium 2.35 mmol/L; Albumin 45 g/L; Total Protein 6.8 g/dL.

Other clinical attributes
- Day -6: Weight: 76 kg; Height: 171 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Colorectal Cancer.

Biospecimens (2 samples)
- Sample MMRF_2597_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -6 days.
- Sample MMRF_2597_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -6 days.
